Somatic mutation profile of tumor specimen TCGA-K1-A3PN-02A (aliquot TCGA-K1-A3PN-02A-11D-A228-09) from TCGA case TCGA-K1-A3PN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 64.7 years (23,631 days).
Specimen TCGA-K1-A3PN-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cfb98e8-2aa9-4a28-a97d-aa282a66e2d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K1-A3PN-10A (Blood Derived Normal), aliquot TCGA-K1-A3PN-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22cef28d-ee49-459a-ac9b-3d5bb3edfc7f

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Nonsense Mutation 2, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 16/16 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABCA13 | c.9104A>C p.Q3035P | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); catalogued as COSV101446913; called by muse, mutect2, varscan2
- ADCY1 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV99811809; called by muse, mutect2, varscan2
- ALOX15B | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66480298; called by muse, mutect2, varscan2
- ANO6 | c.2575G>T p.V859L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); catalogued as COSV100262929; called by muse, varscan2
- ASPG | c.590T>A p.F197Y | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101496378; called by muse, mutect2, varscan2
- C1orf87 | c.966C>G p.D322E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100967020, COSV100967100; called by muse, mutect2, varscan2
- CDHR3 | c.2349T>A p.D783E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100488208, COSV58419658; called by muse, mutect2, varscan2
- CTTN | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as COSV100097530; called by muse, mutect2, varscan2
- DCAF6 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.941); catalogued as rs775825049, COSV100394179; called by muse, mutect2, varscan2
- DLGAP1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1298416995, COSV59793093; called by muse, mutect2, varscan2
- DNAI4 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100925270; called by muse, mutect2, varscan2
- EXPH5 | c.4604C>T p.S1535F | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV56205030, COSV99761402; called by muse, mutect2, varscan2
- FAM83B | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373419492; called by muse, mutect2, varscan2
- HMGCS1 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100284970; called by muse, mutect2, varscan2
- HUWE1 | c.3505A>G p.T1169A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.111); catalogued as COSV99471735; called by muse, mutect2, varscan2
- IK | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101341776; called by muse, mutect2, varscan2
- KIF6 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 17/22 reads (77%) | catalogued as COSV99758370; called by muse, mutect2, varscan2
- KLHL41 | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99500331; called by muse, mutect2, varscan2
- MAGEA11 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1163894836, COSV100290460; called by muse, mutect2, varscan2
- PLCG1 | c.1010+1G>T p.X337_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | catalogued as COSV54817249, COSV99718743; called by muse, mutect2, varscan2
- PPP1R21 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144544742; called by muse, mutect2, varscan2
- PREX1 | c.904A>C p.K302Q | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906199; called by muse, mutect2, varscan2
- PRR5 | c.191T>G p.L64R (on ENST00000336985 / NM_181333.4; = p.L55R on NM_015366.4) | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99134256; called by muse, mutect2, varscan2
- PRRT3 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV99926464; called by muse, varscan2
- RANBP2 | c.4648A>G p.S1550G | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV99311881; called by muse, mutect2
- SEPTIN14 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66429255; called by muse, mutect2, varscan2
- SPATA31D1 | c.1338C>A p.Y446* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100782721; called by muse, mutect2, varscan2
- SPO11 | c.978T>A p.D326E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100625683; called by muse, mutect2, varscan2
- TRIM3 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100624357; called by muse, mutect2, varscan2
- WASHC2C | c.1837G>C p.A613P | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV100313927; called by muse, mutect2, varscan2
- MEIS2 | c.1368C>A p.S456R | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- AP3D1 | c.1848A>T p.P616= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV100642603; called by muse, mutect2, varscan2
- CBWD5 | c.1038C>T p.S346= (on ENST00000382405 / NM_001330668.1; = p.S298= on NM_001024916.3) | Silent (SNP) | VAF 46/481 reads (10%) | called by muse, mutect2
- FILIP1 | c.1011C>A p.G337= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV52731803; called by muse, mutect2
- KRT32 | c.1162C>A p.R388= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV56787394, COSV99862990; called by muse, mutect2, varscan2
- NPAP1 | c.3297C>T p.C1099= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100275209; called by muse, mutect2, varscan2
- OR52W1 | c.918A>G p.R306= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100258633; called by muse, mutect2, varscan2
- PBX3 | c.615C>T p.I205= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100655404; called by muse, mutect2, varscan2
- PTX4 | c.276G>T p.R92= (on ENST00000447419 / NM_001328608.2; = p.R87= on NM_001013658.1) | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV99560373; called by muse, mutect2, varscan2
- SMCHD1 | c.18C>T p.G6= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV99861385; called by muse, mutect2, varscan2
- TRDMT1 | c.666T>C p.C222= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs965892527, COSV100003894; called by muse, mutect2, varscan2
- DCHS2 | n.1899T>C | RNA (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100251566; called by muse, mutect2, varscan2
- MFSD4B | c.*46A>T | 3'UTR (SNP) | VAF 7/8 reads (88%) | catalogued as COSV100920569; called by muse, mutect2
